Somatic mutation profile of tumor specimen MMRF_2267_1_BM_CD138pos (aliquot MMRF_2267_1_BM_CD138pos_T1_KHS5U_L09518) from MMRF case MMRF_2267, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.4 years (28,984 days).
Specimen MMRF_2267_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eb57720-d56d-4db0-be45-69b7209c04c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2267_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2267_1_PB_Whole_C3_KHS5U_L09519; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb935866-f3f8-4678-85a3-bb036e40c04e

The open-access MAF lists 131 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 35, Silent 19, Intron 10, 5'UTR 7, 5'Flank 3, 3'Flank 3, Splice Site 2, RNA 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 55/58 reads (95%) | catalogued as rs387906651, CM115472, COSV52415510; ClinVar: risk factor / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 45/108 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASCC3 | c.4696C>T p.R1566C | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757716813, COSV64972526; called by muse, mutect2, varscan2
- BRCA1 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80356985, COSV58793323; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1281211435, COSV53457814; called by muse, mutect2, varscan2
- CASZ1 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs779297501, COSV100682137; called by muse, mutect2, varscan2
- CHRNB3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51496523; called by muse, mutect2, varscan2
- ERVV-2 | c.1305A>T p.K435N | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); catalogued as rs1157587751; called by muse, mutect2
- EVPL | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs915051955; called by muse, mutect2, varscan2
- FAM47A | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 47/98 reads (48%) | catalogued as COSV100649640; called by muse, mutect2, varscan2
- FAM47B | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.073); catalogued as COSV61457262; called by muse, mutect2, varscan2
- IFIT2 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769134303, COSV51078061, COSV51080184; called by muse, mutect2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 68/72 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IGKV1-8 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541625602; called by muse, mutect2, varscan2
- IGLV3-1 | c.61T>G p.Y21D | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs372924773; called by muse, varscan2
- MMP16 | c.1332G>T p.W444C | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54159646; called by muse, mutect2, varscan2
- MUC16 | c.38003C>T p.P12668L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs922397969; called by muse, mutect2, varscan2
- NOTCH1 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs1440584630; called by muse, mutect2, varscan2
- NTNG2 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62367464, COSV62369130; called by muse, mutect2, varscan2
- OSBP2 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009182762, COSV60243512; called by muse, mutect2, varscan2
- PCDHGC5 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52745397; called by muse, mutect2
- PGGHG | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs1020838547; called by muse, mutect2, varscan2
- PLA2G3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs373302351; called by muse, mutect2, varscan2
- RNF17 | c.2744A>G p.N915S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs988811685; called by muse, mutect2, varscan2
- SCN7A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200874141; called by muse, mutect2, varscan2
- SFXN1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs1361076036; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374628239; called by muse, mutect2, varscan2
- SYT8 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs369451697; called by muse, mutect2, varscan2
- TTN | c.31513G>A p.A10505T (on ENST00000591111; = p.A9578T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | PolyPhen benign (0); catalogued as COSV60179193; called by muse, mutect2, varscan2
- ULK1 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as rs200414567, COSV100416775; called by muse, mutect2, varscan2
- XIRP2 | c.5615C>G p.S1872C (on ENST00000628543; = p.S2047C on NM_152381.6) | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs191159891, COSV54679976, COSV54712409; called by muse, mutect2, varscan2
- XIRP2 | c.6004G>A p.D2002N (on ENST00000628543; = p.D2177N on NM_152381.6) | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs113038974; called by muse, mutect2, varscan2
- AP2M1 | c.1173+2T>G p.X391_splice | Splice Site (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- C8orf58 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- CRYBG2 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSMD3 | c.8441-1del p.X2814_splice (on ENST00000297405 / NM_001363185.1; = p.X2645_splice on NM_052900.3) | Splice Site (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- DNAAF2 | c.1976T>G p.V659G | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- EIF2S3 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GUCY2C | c.2884A>G p.I962V | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST5 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HUWE1 | c.9277G>A p.A3093T | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRBA2 | c.259_281del p.R87Gfs*6 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- LIMD2 | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- MCM4 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.4549C>A p.Q1517K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PPRC1 | c.2864T>C p.V955A | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPGRIP1 | c.3139A>G p.S1047G | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TFB1M | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRIM41 | c.824A>T p.Q275L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- USP34 | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZNF284 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF648 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- B3GNTL1 | c.996C>T p.C332= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as rs572427361; called by muse, mutect2, varscan2
- CKAP2L | c.2064G>A p.R688= | Silent (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- GPR148 | c.420C>T p.T140= | Silent (SNP) | VAF 98/224 reads (44%) | catalogued as rs200395856; called by muse, mutect2, varscan2
- IPMK | c.129C>T p.L43= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- ITGA9 | c.2998C>T p.L1000= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- KIAA2026 | c.2787A>C p.T929= | Silent (SNP) | VAF 102/164 reads (62%) | catalogued as COSV101199053; called by muse, mutect2, varscan2
- MAGEE2 | c.441T>C p.I147= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- MBL2 | c.420G>C p.L140= | Silent (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- MUC5B | c.12660G>A p.V4220= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as rs1174350219; called by muse, mutect2, varscan2
- NRXN3 | c.3213C>T p.F1071= (on ENST00000335750 / NM_001330195.2; = p.F698= on NM_004796.6) | Silent (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- PTPN14 | c.2319C>T p.P773= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs201409194; called by muse, mutect2, varscan2
- RAMP1 | c.342G>A p.P114= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as rs745619605; called by muse, mutect2, varscan2
- SARS1 | c.234G>A p.E78= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- SLC4A3 | c.1137C>A p.A379= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99813148; called by muse, mutect2, varscan2
- SLC6A5 | c.747G>T p.V249= | Silent (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- TENM4 | c.1521G>A p.A507= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1048496120; called by muse, mutect2, varscan2
- WDHD1 | c.1128C>T p.I376= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as COSV100777612; called by muse, mutect2, varscan2
- ZNF503 | c.1914C>A p.T638= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.2061T>C p.Y687= | Silent (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- ABCC9 | c.*1049T>G | 3'UTR (SNP) | VAF 48/53 reads (91%) | called by muse, mutect2, varscan2
- AC008969.1 | n.3681G>A | RNA (SNP) | VAF 43/91 reads (47%) | catalogued as rs988886671; called by muse, mutect2, varscan2
- AC068533.4 | c.564-12920del | Intron (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- AFMID | c.-54C>T | 5'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs878887356; called by muse, varscan2
- AP3B2 | c.360+467G>T | Intron (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- C16orf54 | c.*743T>A | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- CACNA1C | c.3828+2138C>T | Intron (SNP) | VAF 127/152 reads (84%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949325 T>C | 3'Flank (SNP) | VAF 43/95 reads (45%) | catalogued as rs1471533081; called by muse, mutect2, varscan2
- CCDC93 | c.*839C>G | 3'UTR (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- CDC5L | c.-81C>T | 5'UTR (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- CDH19 | c.*2900A>G | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- CDK12 | c.*3051G>T | 3'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- CHMP3 | chr2:86563450 C>T | 5'Flank (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- COLQ | c.*405T>A | 3'UTR (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- CTR9 | c.-42G>A | 5'UTR (SNP) | VAF 34/66 reads (52%) | catalogued as rs772348534; called by muse, mutect2, varscan2
- DAG1 | c.*2340A>G | 3'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as rs1293047875; called by muse, mutect2, varscan2
- DOCK2 | c.-8G>A | 5'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- EFEMP1 | c.*749C>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- EPHA7 | c.832+711del | Intron (DEL) | VAF 22/107 reads (21%) | called by pindel, varscan2
- EPHA7 | c.832+705C>G | Intron (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
- F2RL2 | c.*89C>T | 3'UTR (SNP) | VAF 103/203 reads (51%) | catalogued as rs968441631; called by muse, mutect2, varscan2
- FLRT3 | c.*2455G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- FOXI2 | chr10:127736684 C>T | 5'Flank (SNP) | VAF 78/180 reads (43%) | called by muse, mutect2, varscan2
- GABRE | c.*756T>A | 3'UTR (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- GOLGA4 | c.1545+91C>T | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- HNF4G | c.*167C>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- KCNK10 | c.*1523G>A | 3'UTR (SNP) | VAF 69/69 reads (100%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*4555G>T | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- LGI2 | c.*2733C>T | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- LPCAT2 | c.*1227A>G | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- MRO | c.*669C>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs900999090; called by muse, mutect2
- MTHFD1 | c.1815+81A>G | Intron (SNP) | VAF 89/95 reads (94%) | called by muse, mutect2, varscan2
- NAT1 | c.*216_*218del | 3'UTR (DEL) | VAF 6/68 reads (9%) | catalogued as rs869146186; called by mutect2, pindel
- NTRK2 | c.1585+7558A>C | Intron (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- POLK | c.*971G>A | 3'UTR (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- POU2F1 | c.*8901T>C | 3'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- PPP1R3C | c.*442G>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- PSG9 | c.*167A>T | 3'UTR (SNP) | VAF 48/51 reads (94%) | catalogued as rs1383748135; called by muse, mutect2, varscan2
- PTGDS | c.-16G>A | 5'UTR (SNP) | VAF 31/84 reads (37%) | catalogued as rs780608359, COSV99811838; called by muse, mutect2, varscan2
- RBFOX1 | chr16:7711903 A>C | 3'Flank (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- SCIN | c.*769A>T | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- SCMH1 | c.*654C>T | 3'UTR (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- SCML4 | c.*1064C>T | 3'UTR (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- SCUBE1 | c.844+140G>T | Intron (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- SERTM1 | c.*531A>T | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1626G>A | RNA (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- SMOC2 | c.*51C>G | 3'UTR (SNP) | VAF 181/387 reads (47%) | called by muse, mutect2, varscan2
- SP100 | c.*908A>G | 3'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- SP5 | chr2:170712772 C>T | 5'Flank (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- SPNS3 | c.*85G>A | 3'UTR (SNP) | VAF 19/43 reads (44%) | catalogued as rs72821822; called by muse, mutect2, varscan2
- TAP2 | chr6:32821876 T>C | 3'Flank (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- TARM1 | c.*57C>T | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2
- TBC1D25 | c.*784A>G | 3'UTR (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- TBL1X | c.*3401A>G | 3'UTR (SNP) | VAF 64/119 reads (54%) | called by muse, mutect2, varscan2
- TENT5C | c.*690_*692del | 3'UTR (DEL) | VAF 40/96 reads (42%) | called by mutect2, pindel, varscan2
- TIPARP | c.*806G>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- TMSB4X | c.-41C>A | 5'UTR (SNP) | VAF 65/124 reads (52%) | catalogued as COSV66081674; called by muse, mutect2, varscan2
- UBIAD1 | c.-41T>A | 5'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- WDR48 | c.*1649_*1650del | 3'UTR (DEL) | VAF 4/24 reads (17%) | catalogued as rs1185062448; called by pindel, varscan2
- ZNF252P | n.245+4143A>G | Intron (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
